Surgical pathology report (de-identified scan), TCGA case TCGA-06-0939, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0939-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

06-0939-01A

CLINICAL HISTORY

[REDACTED] with [REDACTED] and seizure, has an intraaxial, complex, cystic lesion with peripheral enhancement and associated edema.

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Brain, excision biopsy

B: Brain, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A. Brain, left parietal lobe, excisional biopsy:

1. Glioblastoma.
2. MIB-1 proliferation index: 9%.

B. Brain, left parietal lobe, excisional biopsy: Infiltrating glioma.

See Microscopy Description and Comment.

COMMENT

In part A there is an astrocytic neoplastic proliferation that has prominent gemistocytic features. The neoplasm has nuclear anaplasia, mitotic figures, microvascular cellular proliferation, and focal tumor necrosis, i.e. histological features of glioblastoma. The MIB-1 proliferation index is high at about 9%.

Part B is portions of cerebral cortex and adjacent white matter in which there is sparse infiltration by neoplastic cells, mostly in the white matter.

INTRA-OPERATIVE CONSULTATION

A.

[page 2 of 2]
Brain, excision biopsy, touch prep and smears: High histological grade glioma (C/W glioblastoma). Touch preparation smears performed at Hospital and results reported to the Physician of Record.

GROSS DESCRIPTION

A.

"Brain tumor," received fresh, two fragments, 0.4 and 0.6 cm. across, each. Semi firm, brown and grayish-white. In total, A1 and A2.

B.

SPECIMEN: Brain tumor.

FIXATIVE: None.

GENERAL: A 1.8 x 1.0 x 0.7 cm., 0.63 gm. fragment of soft pale red-tan to gray-tan brain tissue.

SECTIONS: B1 all submitted.

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: On part A, the GFAP demonstrates an abundance of neoplastic gemistocytes. Only about 5% of cells express weakly the p53 protein. The CD163 depicts frequent positive cells (phagocytic). With the MIB-1 there is a proliferation index of about 9%. On part B, the CD163 demonstrates frequent positive cells, very scant in the cerebral cortex. The MIB-1 depicts frequent cycling cells in hypercellular white matter areas.

The immunoreresults are consistent with an astrocytic neoplastic proliferation, which is sparsely infiltrative in part B.

ICD-9(s):

239.6 239.6

Histo Data

Part A: Brain, excision biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
CD163 Vector x 1	1		
mGFAP-DA x 1	1		
H/E x 1	1		
MIB1-DA x 1	1		
P53DO7 x 1	1		
TPS H/E x 1	1		
H/E x 1	2		

Part B: Brain, excision biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
CD163 Vector x 1	1		
H/E x 1	1		
MIB1-DA x 1	1		

Source: NCI Genomic Data Commons file 0f80c07b-4e6a-4c30-9b85-16292216b2a4 (TCGA-06-0939.DB0CE8DC-CE11-4574-9F60-DF59B7AF1CC3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).